Somatic mutation profile of tumor specimen MP2PRT-PAURJE-TMP1-A (aliquot MP2PRT-PAURJE-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAURJE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.3 years (1,553 days).
Specimen MP2PRT-PAURJE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6fa966a-3800-4e65-9e7c-86ae0e6d86ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAURJE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAURJE-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62591a32-53bb-4f40-8412-fb56b18b8255

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 14, Silent 6, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.5521C>T p.R1841C | Missense Mutation (SNP) | VAF 110/271 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.582); catalogued as rs367621359; called by muse, mutect2, varscan2
- ANKS6 | c.1720C>T p.R574W | Missense Mutation (SNP) | VAF 156/383 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs1451220911, COSV62051281; called by muse, mutect2, varscan2
- FAM86B2 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 98/592 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as rs763209343; called by muse, mutect2, varscan2
- FLT3 | c.1781T>C p.F594S | Missense Mutation (SNP) | VAF 106/305 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV54052730; called by muse, mutect2, varscan2
- GJA8 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 48/416 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs782253888, COSV53787656; called by muse, mutect2
- ITLN2 | c.679G>T p.D227Y | Missense Mutation (SNP) | VAF 118/286 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV63537690; called by muse, mutect2, varscan2
- MAP1S | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 88/652 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs759397044; called by muse, mutect2, varscan2
- MTG2 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 86/230 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs761982766, COSV100895120, COSV100895169; called by muse, mutect2, varscan2
- NMBR | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 49/624 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.417); catalogued as rs570950524, COSV57800824; called by muse, mutect2
- TAF1L | c.3730C>T p.R1244W | Missense Mutation (SNP) | VAF 180/469 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758614619, COSV54267778; called by muse, mutect2, varscan2
- ZNF214 | c.984G>T p.E328D | Missense Mutation (SNP) | VAF 62/220 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV53483439; called by muse, mutect2, varscan2
- IFNA16 | c.209A>T p.Q70L | Missense Mutation (SNP) | VAF 75/171 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- IGHV3-7 | chr14:106062148 GTCT>TCTGTAGGGGGCTTCCGC | Missense Mutation (INS) | VAF 26/259 reads (10%) | called by pindel, varscan2*
- SMG7 | c.1634T>C p.V545A | Missense Mutation (SNP) | VAF 131/337 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- TMEM143 | c.1034_1035insGGCTTATCG p.R345_S346insAYR | In Frame Ins (INS) | VAF 176/459 reads (38%) | called by mutect2, pindel, varscan2
- ALDH3B1 | c.177G>A p.S59= | Silent (SNP) | VAF 89/231 reads (39%) | catalogued as rs754267666; called by muse, mutect2, varscan2
- ARHGEF28 | c.1059G>A p.P353= | Silent (SNP) | VAF 36/272 reads (13%) | catalogued as rs745869276, COSV55252481; called by muse, mutect2, varscan2
- EP300 | c.3888C>G p.T1296= | Silent (SNP) | VAF 132/279 reads (47%) | called by muse, mutect2, varscan2
- IGHV4-61 | chr14:106639100 CTCACCTCCCCTCACTGTGT>ATGGCCTCCCCTCACTGTGTCTCC | Silent (INS) | VAF 17/211 reads (8%) | called by pindel, varscan2*
- PAPPA2 | c.3867C>T p.P1289= | Silent (SNP) | VAF 77/324 reads (24%) | catalogued as rs370502405; called by muse, mutect2, varscan2
- POGK | c.171C>T p.S57= | Silent (SNP) | VAF 127/274 reads (46%) | catalogued as COSV63311399; called by muse, mutect2, varscan2
